Somatic mutation profile of tumor specimen 0DKPXF from CCDI case PBBYIT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 14.5 years (5,284 days).
Specimen 0DKPXF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ff29064-be06-4c00-a08b-d295d14c6033.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKPWD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4dc7ab3-a6e6-4a9d-b868-29a5a813b62f

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADIPOR1 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 558/947 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); catalogued as COSV100579353; called by muse, mutect2, varscan2
- ATP2C1 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 100/227 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs200576649, COSV100146819; called by muse, mutect2, varscan2
- GRIA3 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 293/314 reads (93%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs757586471, CM151043; called by muse, mutect2, varscan2
- HEPACAM2 | c.143C>T p.A48V (on ENST00000394468 / NM_001039372.4; = p.A36V on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 280/558 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV59060295; called by muse, mutect2, varscan2
- SUGP1 | c.273G>T p.Q91H | Missense Mutation (SNP) | VAF 311/682 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MFSD12 | c.393C>T p.Y131= | Silent (SNP) | VAF 270/534 reads (51%) | catalogued as rs201884574; called by muse, mutect2, varscan2
- KDM5A | c.1774-52G>T | Intron (SNP) | VAF 174/332 reads (52%) | called by muse, mutect2, varscan2
- NR1I2 | c.-23+412C>A | Intron (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- POLR2E | c.58-48C>T | Intron (SNP) | VAF 157/329 reads (48%) | catalogued as rs1283971374; called by muse, mutect2, varscan2
